Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9ZI, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9ZI-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

- A. Lymph nodes, right pelvic, dissection: Seven lymph nodes negative for carcinoma (0/7).
- B. Lymph nodes, left pelvic, dissection: Three lymph nodes negative for carcinoma (0/3).
- C. Prostate and bilateral seminal vesicles, radical prostatectomy: Prostatic adenocarcinoma, Gleason grade 5+4, score=9, with bilateral involvement, extraprostatic extension and invasion into right seminal vesicle, negative margins; see comment.

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS 61.9
J 1/28/14

COMMENT:

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** Left posterior midgland - slide C10, right posterior midgland - slides C6 and C7; right posterior base - slide C8; right anterior midgland - slides C3 and C4; right anterior base - slides C5 and C17.
- **Estimated volume of tumor:** 5.7 cubic centimeter.
- **Gleason score:** 5+4; primary pattern 5, secondary pattern 4.
- **Estimated volume > Gleason pattern 3:** 100%.
- **Involvement of capsule:** Tumor invades capsule (Right anterior midgland - slides C3 and C4; right posterior midgland - slide C7; right posterior base - slides C8 and C17).
- **Extraprostatic extension:** Present, limited in extent (right posterior midgland - slide C7; right posterior base - slides C8 and C17).
- **Margin status for tumor:** Negative (tumor is <0.1 mm from margin, slide C8).
- **Margin status for benign prostate glands:** No benign glands present at inked excision margins.
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** None.
- **Tumor involvement of seminal vesicle:** Present: Right side.

[page 2 of 3]
- **Lymphovascular invasion:** Present (slide C7).
- **Perineural infiltration:** Present.
- **Lymph node status:** Negative, total number of nodes examined: 10.
- **AJCC/UICC stage:** pT3bN0.

Dr. [redacted] reviewed slide C7 and concurs with the diagnosis of prostatic adenocarcinoma, Gleason grade 5+4.

Specimen(s) Received

A: Right pelvic lymph nodes

B: Left pelvic lymph nodes

C: Prostate & bilateral seminal vesicles (fresh)

Clinical History

The patient is a [redacted]-year-old man with prostatic adenocarcinoma in the right apex, right mid, right base, and right nodule, with Gleason grade 4+5=9 ([redacted]). The patient now undergoes robot-assisted radical prostatectomy and bilateral pelvic lymph node dissections.

Gross Description

The specimen is received in three parts, each labeled with the patient's name and medical record number. Parts A and B are received in formalin. Part C is received fresh.

Part A, additionally labeled "right pelvic lymph nodes," consists of a piece of irregular, unoriented, yellow-tan fibrofatty tissue (4.5 x 3 x 0.8 cm) that contains five uniformly pink-tan soft/firm lymph node candidates (2 cm-0.5 cm). The entire specimen is submitted as follows:

Cassette A1: Intact largest lymph node candidate.
Cassette A2: Four intact smaller lymph node candidates.
Cassette A3: Fibrofatty tissue.

Part B, additionally labeled "left pelvic lymph nodes," consists of a piece of irregular, unoriented, yellow-tan fibrofatty tissue (4 x 2.7 x 1 cm) that contains three uniformly pink-tan soft/firm lymph nodes (3 cm, 0.5 cm, and 0.4 cm). The cut surface of the largest lymph node appears homogenous white-pink. The entire specimen is submitted as follows:

Cassettes B1-B2: Largest lymph node, serially sectioned.
Cassette B3: Two intact smaller lymph nodes.
Cassette B4: Fibrofatty tissue.

Part C is labeled "prostate and bilateral seminal vesicles," and consists of a radical prostatectomy specimen (53 gm; 4 cm from apex to base x 5 cm in width x 3.5 cm from anterior to posterior).

GROSS PATHOLOGIC FINDINGS: There are multiple, tan, rubbery nodules (largest 1.3 x 1 x 1 cm) located centrally. In slices 1-8, there is a white-tan firm mass (3.2 x 2.5 x 1.2 cm) with an irregular border in the peripheral aspect of the right lobe that does not extend across the midline. The mass abuts the right lateral and right posterior margins.

The anterior fibrous stroma is red-tan, roughened, and open; the remaining capsule is intact. The remaining prostatic parenchyma is tan. The seminal vesicle/vas deferens bundles (right 2.5 x 2.5 x 0.7 cm; left 2.5 x 2 x 0.7 cm) are soft, lobulated, and red-tan, without obvious mass. Some of the fresh prostate tissue is taken by the [redacted]. The non-sectioned slices are embedded for research purposes.

ORIENTED BY: Anatomic landmarks; seminal vesicles, urethra.

INKING: Right anterior in green, left anterior in blue, posterior in black.

POTENTIAL STUDIES: Snap-frozen.

GROSS PHOTOGRAPHS: Yes.

[page 3 of 3]
CASSETTES: Representative sections are submitted as follows:

Apical margins, entirely submitted in perpendicular sections

C1: Right apex.

C2: Left apex.

Right anterior quadrant

C3: Slice 2, with white-tan firm mass.

C4: Slice 4, with white-tan firm mass and portion of the largest nodule located centrally.

C5: Slice 7.

Right posterior quadrant

C6: Slice 2, with white-tan firm mass.

C7: Slice 4, with white-tan firm mass and portion of the largest nodule located centrally.

C8: Slice 7, with white-tan firm mass.

Left posterior quadrant

C9: Slice 2.

C10: Slice 4.

C11: Slice 7.

Left anterior quadrant

C12: Slice 2.

C13: Slice 4.

C14: Slice 7.

Bladder margins, entirely submitted in perpendicular sections

C15: Right.

C16: Left.

Prostatic/seminal vesicle junction and cross-section of vas deferens

C17: Right.

C18: Left.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically signed on [redacted]

Source: NCI Genomic Data Commons file 032b2384-fdad-4236-9db9-5adf92b2c2f0 (TCGA-V1-A9ZI.7C3EC6A6-C005-4877-A6C8-C3174709A3FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).